Somatic mutation profile of tumor specimen 0DPE9L from CCDI case PBCDJY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ganglioglioma, NOS; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 17.2 years (6,285 days).
Specimen 0DPE9L: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 96bb94b5-6868-438a-bbb8-6d8fd0c91356.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPE95 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/195e05ee-e2e5-444d-9933-54cbbaa849ad

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 6, Silent 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 228/493 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- SASH1 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 94/314 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765839775; called by muse, varscan2
- SUPT7L | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 30/572 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as rs766274406; called by muse, mutect2
- TOPAZ1 | c.3314G>A p.R1105H | Missense Mutation (SNP) | VAF 41/542 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as rs1441853650, COSV59065277; called by muse, mutect2
- WDR75 | c.2246C>A p.S749Y | Missense Mutation (SNP) | VAF 33/469 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV59104992; called by muse, mutect2
- DOT1L | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 41/714 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- RUNX1T1 | c.1283_1289dup p.E431Afs*22 (on ENST00000265814 / NM_001198628.1; = p.E404Afs*22 on NM_004349.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 87/270 reads (32%) | called by mutect2, varscan2
- CCDC92 | c.252A>G p.L84= | Silent (SNP) | VAF 42/968 reads (4%) | catalogued as rs543085766; called by muse, mutect2
- IL36G | c.216G>A p.G72= | Silent (SNP) | VAF 17/412 reads (4%) | called by muse, mutect2
